Somatic mutation profile of tumor specimen TCGA-05-5428-01A (aliquot TCGA-05-5428-01A-01D-1625-08) from TCGA case TCGA-05-5428, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 57.7 years (21,061 days).
Specimen TCGA-05-5428-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5eaa4117-0c17-40a6-94a9-ad229a8e5250.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-05-5428-10A (Blood Derived Normal), aliquot TCGA-05-5428-10A-01D-1625-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aa57de4e-7f8f-4c9c-a185-4ab87bb9e438

The open-access MAF lists 407 somatic variants for this specimen: 305 protein-altering or splice-affecting, 92 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 260, Silent 92, Nonsense Mutation 28, Splice Site 8, Frame Shift Del 5, Intron 4, Frame Shift Ins 2, Splice Region 2, 5'UTR 2, 3'Flank 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1900G>A p.D634N (on ENST00000288602 / NM_001374244.1; = p.D594N on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as rs397516896, COSV56061673, COSV56106240, COSV56184663; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PAX6 | c.917-2A>T p.X306_splice | Splice Site (SNP) | VAF 7/45 reads (16%) | catalogued as rs587776571, CS951501, COSV53793526, COSV53795040; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.713G>A p.C238Y | Missense Mutation (SNP) | VAF 17/36 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882005, CM034930, COSV52661646, COSV52706816, COSV52804264; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- AASDH | c.945A>T p.L315F | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52706586; called by muse, mutect2, varscan2
- ABCA7 | c.5536G>C p.A1846P | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV54029665; called by muse, mutect2, varscan2
- ACAD11 | c.1930G>A p.E644K | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53896375; called by muse, mutect2, varscan2
- ACOT1 | c.572A>G p.Y191C | Missense Mutation (SNP) | VAF 42/78 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as COSV58572762; called by muse, mutect2, varscan2
- ACTN3 | c.1140C>A p.N380K | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.75); PolyPhen benign (0.029); catalogued as COSV72207593, COSV72207663; called by muse, mutect2, varscan2
- ADAD1 | c.1395G>A p.M465I | Missense Mutation (SNP) | VAF 32/172 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV56643538; called by muse, mutect2, varscan2
- ADAM17 | c.722G>A p.R241K | Missense Mutation (SNP) | VAF 13/264 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.045); catalogued as COSV60398910; called by muse, mutect2
- ADAMTS18 | c.3210G>C p.L1070F | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as COSV51410560; called by muse, mutect2, varscan2
- ADCY8 | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV53908135; called by muse, mutect2, varscan2
- ADGRF5 | c.813C>T p.I271= | Splice Region (SNP) | VAF 14/94 reads (15%) | catalogued as COSV51933977; called by muse, mutect2, varscan2
- AGAP2 | c.3025C>A p.R1009S (on ENST00000547588 / NM_001122772.2; = p.R653S on NM_014770.4) | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1432619645, COSV57728143; called by muse, mutect2, varscan2
- ALOXE3 | c.1486C>T p.R496W | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as rs867780319, COSV59075685; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKMY1 | c.2615G>T p.G872V | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.105); catalogued as COSV56034190; called by muse, mutect2, varscan2
- ANKRD24 | c.476G>T p.G159V | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53670551, COSV53677895; called by muse, mutect2, varscan2
- AOC1 | c.1328C>A p.A443E | Missense Mutation (SNP) | VAF 48/73 reads (66%) | SIFT tolerated (0.05); PolyPhen benign (0.308); catalogued as rs766971033, COSV62868602, COSV62870832; called by muse, mutect2, varscan2
- AOC2 | c.192G>C p.L64F | Missense Mutation (SNP) | VAF 83/354 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53199222; called by muse, mutect2, varscan2
- AP2A1 | c.2887G>C p.E963Q | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.404); catalogued as COSV58241644; called by muse, mutect2
- ARHGEF7 | c.971C>T p.S324F (on ENST00000375741 / NM_001113511.2; = p.S146F on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV54543480; called by muse, mutect2, varscan2
- ARID4B | c.1792G>T p.E598* | Nonsense Mutation (SNP) | VAF 52/146 reads (36%) | catalogued as COSV51603303; called by muse, mutect2, varscan2
- ARID4B | c.274G>T p.V92F | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99935817; called by muse, mutect2, varscan2
- ASXL3 | c.1026G>C p.K342N | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99325403; called by muse, mutect2, varscan2
- ASXL3 | c.1027G>T p.E343* | Nonsense Mutation (SNP) | VAF 9/27 reads (33%) | catalogued as COSV99324027, COSV99326364; called by muse, mutect2, varscan2
- ASXL3 | c.3203G>T p.R1068L | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV52466416; called by muse, mutect2, varscan2
- ATP7A | c.4161G>A p.W1387* | Nonsense Mutation (SNP) | VAF 60/108 reads (56%) | catalogued as COSV58446509; called by muse, mutect2, varscan2
- BCAS1 | c.1690C>T p.R564W | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147771144; called by muse, mutect2, varscan2
- BCL11A | c.1621C>A p.L541M (on ENST00000335712 / NM_001365609.1; = p.L575M on NM_018014.4) | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.737); catalogued as COSV59630178; called by muse, mutect2, varscan2
- BHMT | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.246); catalogued as COSV57154381; called by muse, mutect2, varscan2
- BMPER | c.1159C>A p.Q387K | Missense Mutation (SNP) | VAF 63/161 reads (39%) | SIFT tolerated (0.5); PolyPhen benign (0.03); catalogued as COSV51818730, COSV99778921; called by muse, mutect2, varscan2
- BRINP3 | c.1361C>A p.P454Q | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV66524506; called by muse, mutect2, varscan2
- C1orf105 | c.199-1G>T p.X67_splice | Splice Site (SNP) | VAF 61/148 reads (41%) | catalogued as COSV62959323; called by muse, mutect2, varscan2
- C2CD3 | c.2379G>C p.Q793H | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as COSV58093116; called by muse, mutect2, varscan2
- C2orf16 | c.1258C>T p.P420S | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT tolerated (0.9); PolyPhen benign (0.023); catalogued as COSV68646112; called by muse, mutect2, varscan2
- C4orf17 | c.341C>A p.P114H | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100430969; called by muse, mutect2, varscan2
- CALCB | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60834184, COSV60834476; called by muse, mutect2, varscan2
- CALCRL | c.349A>T p.S117C | Missense Mutation (SNP) | VAF 136/265 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV66474942; called by muse, mutect2, varscan2
- CAMKK2 | c.212A>C p.D71A | Missense Mutation (SNP) | VAF 27/37 reads (73%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as COSV100243050; called by muse, mutect2, varscan2
- CARD11 | c.3195C>G p.I1065M | Missense Mutation (SNP) | VAF 53/126 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV67798169; called by muse, mutect2, varscan2
- CARD11 | c.489G>C p.K163N | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.093); catalogued as COSV62717607; called by muse, mutect2
- CASP8AP2 | c.2543A>G p.N848S | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as rs1192829449, COSV52747014; called by muse, mutect2, varscan2
- CASR | c.2935G>A p.V979M (on ENST00000490131; = p.V1056M on NM_000388.4) | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.003); catalogued as COSV56135975; called by muse, mutect2, varscan2
- CCDC106 | c.538G>T p.D180Y | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV58273642, COSV58273955; called by muse, mutect2, varscan2
- CCDC178 | c.1654C>T p.Q552* | Nonsense Mutation (SNP) | VAF 13/58 reads (22%) | catalogued as COSV55774255; called by muse, mutect2, varscan2
- CCDC178 | c.1046G>T p.S349I | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV55774284; called by muse, mutect2, varscan2
- CCK | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs370480453; called by muse, mutect2, varscan2
- CCT8L2 | c.540G>T p.L180F | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as COSV63462422; called by muse, mutect2, varscan2
- CDC20 | c.131G>T p.R44L | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.041); catalogued as COSV60522128; called by muse, mutect2, varscan2
- CDH1 | c.2213A>G p.K738R | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs768163102, COSV55732886; called by muse, mutect2, varscan2
- CDH10 | c.1875G>T p.L625= | Splice Region (SNP) | VAF 29/158 reads (18%) | catalogued as COSV52572288; called by muse, mutect2, varscan2
- CDH18 | c.1684G>T p.D562Y | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); catalogued as COSV56914692, COSV56923003; called by muse, mutect2, varscan2
- CDH19 | c.1487G>A p.R496K | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.057); catalogued as COSV50959242; called by muse, mutect2, varscan2
- CDHR5 | c.2335G>C p.E779Q (on ENST00000358353 / NM_001171968.2; = p.E785Q on NM_021924.5) | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV57642993, COSV57646741; called by muse, mutect2
- CELSR2 | c.8133C>A p.D2711E | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV54771911; called by muse, mutect2, varscan2
- CFAP58 | c.1439C>A p.S480* | Nonsense Mutation (SNP) | VAF 14/90 reads (16%) | catalogued as COSV100866123; called by muse, mutect2, varscan2
- CHD4 | c.1586A>C p.Q529P (on ENST00000357008 / NM_001363606.2; = p.Q542P on NM_001273.5) | Missense Mutation (SNP) | VAF 58/163 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as COSV58901301; called by muse, mutect2, varscan2
- CILK1 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.027); catalogued as rs967592463, COSV63154203; called by muse, varscan2
- CLCN1 | c.2482C>A p.L828M | Missense Mutation (SNP) | VAF 39/68 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780637101, COSV58369889; called by muse, mutect2, varscan2
- CLCN6 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.135); catalogued as COSV56740161; called by muse, mutect2, varscan2
- CLIP4 | c.1687G>T p.E563* | Nonsense Mutation (SNP) | VAF 24/93 reads (26%) | catalogued as COSV60748604, COSV60749188; called by muse, mutect2, varscan2
- CLIP4 | c.1688A>T p.E563V | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as COSV100192037; called by muse, mutect2, varscan2
- CMPK2 | c.1108G>C p.D370H | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.832); catalogued as COSV56774713; called by muse, mutect2, varscan2
- CNGA2 | c.1122G>A p.M374I | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV61703488; called by muse, mutect2, varscan2
- CNTN4 | c.2775G>C p.K925N | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.538); catalogued as COSV61873213; called by muse, mutect2, varscan2
- CNTN6 | c.334C>T p.R112W | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs374599521; called by muse, mutect2, varscan2
- COL12A1 | c.8923G>T p.G2975* | Nonsense Mutation (SNP) | VAF 47/191 reads (25%) | catalogued as COSV59396219, COSV59408657; called by muse, mutect2, varscan2
- CORO1B | c.439G>A p.V147M | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1020357148, COSV100396607; called by muse, mutect2, varscan2
- CPZ | c.1777C>T p.H593Y (on ENST00000360986 / NM_001014447.3; = p.H582Y on NM_003652.3) | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV59923059; called by muse, mutect2, varscan2
- CROT | c.1075G>T p.V359L | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as COSV58974342; called by muse, mutect2, varscan2
- CSAG1 | c.167+2C>T p.X56_splice | Splice Site (SNP) | VAF 31/105 reads (30%) | catalogued as rs1556830726, COSV63400327; called by muse, mutect2, varscan2
- CSMD2 | c.3166G>A p.G1056S | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as COSV53912951; called by muse, mutect2, varscan2
- CSMD3 | c.379C>A p.H127N | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT tolerated (0.79); PolyPhen probably damaging (0.968); catalogued as COSV52183648; called by muse, mutect2, varscan2
- CTDP1 | c.343A>T p.S115C | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV50003357; called by muse, mutect2, varscan2
- CTPS2 | c.1024C>G p.L342V | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV63722608; called by muse, mutect2
- CUBN | c.8332C>T p.Q2778* | Nonsense Mutation (SNP) | VAF 14/83 reads (17%) | catalogued as rs1032830399, COSV64715958; called by muse, mutect2, varscan2
- CUBN | c.7619G>A p.G2540E | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64715962; called by muse, mutect2, varscan2
- CUX1 | c.3245A>G p.E1082G | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as COSV52899912; called by muse, mutect2, varscan2
- CYP2W1 | c.982C>T p.R328C | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs769250658, COSV58269144; called by muse, mutect2, varscan2
- CYP4F11 | c.1249G>T p.G417C | Missense Mutation (SNP) | VAF 56/72 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56127013; called by muse, varscan2
- DAB2 | c.697G>C p.D233H | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV57914457; called by muse, mutect2
- DACT1 | c.500G>T p.G167V | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774451791, COSV60020801; called by muse, mutect2, varscan2
- DCDC1 | c.4396C>G p.R1466G (on ENST00000597505 / NM_001367979.1; = p.R573G on NM_020869.3) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.13); catalogued as COSV100337933, COSV100338441, COSV57998997; called by muse, mutect2
- DCLK3 | c.291G>T p.R97S | Missense Mutation (SNP) | VAF 73/196 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV69363177; called by muse, mutect2, varscan2
- DIXDC1 | c.1379G>T p.R460L (on ENST00000440460 / NM_001037954.4; = p.R249L on NM_033425.4) | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.654); catalogued as COSV59461927; called by muse, mutect2, varscan2
- DLG5 | c.1816G>A p.D606N | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746763859, COSV64948031; called by muse, mutect2
- DLGAP2 | c.1529C>A p.S510Y | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV101422182; called by muse, mutect2
- DNAH5 | c.4117-1G>T p.X1373_splice | Splice Site (SNP) | VAF 58/102 reads (57%) | catalogued as COSV54225170; called by muse, mutect2, varscan2
- DOCK5 | c.238G>T p.V80L | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs368748190, COSV52402113; called by muse, mutect2, varscan2
- DSCAM | c.2524G>T p.V842L | Missense Mutation (SNP) | VAF 75/157 reads (48%) | SIFT tolerated (0.34); PolyPhen benign (0.068); catalogued as COSV68026844; called by muse, mutect2, varscan2
- EFCAB3 | c.713C>A p.S238* | Nonsense Mutation (SNP) | VAF 19/110 reads (17%) | catalogued as rs1429608472, COSV59502115; called by muse, mutect2, varscan2
- EPB41L3 | c.89G>T p.G30V | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0.086); catalogued as COSV59453832; called by muse, mutect2, varscan2
- EPHB6 | c.1811C>G p.A604G | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT tolerated (0.97); PolyPhen benign (0.019); catalogued as COSV63891776; called by muse, varscan2
- EYS | c.1010C>T p.S337L | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as COSV60985790; called by muse, varscan2
- FAM171A1 | c.1646A>T p.E549V | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV65316149; called by muse, mutect2, varscan2
- FAT3 | c.9610A>T p.S3204C | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.393); catalogued as COSV53111175; called by muse, mutect2, varscan2
- FCRL4 | c.637G>C p.E213Q | Missense Mutation (SNP) | VAF 34/220 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.596); catalogued as COSV54860901, COSV54862331; called by muse, mutect2, varscan2
- FKTN | c.949G>C p.D317H | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56309830, COSV56310240; called by muse, mutect2, varscan2
- FLG | c.5330C>A p.S1777Y | Missense Mutation (SNP) | VAF 135/422 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV64240084, COSV64241923; called by muse, mutect2, varscan2
- FRMD6 | c.1420G>T p.E474* (on ENST00000344768 / NM_001267046.2; = p.E466* on NM_152330.4) | Nonsense Mutation (SNP) | VAF 14/59 reads (24%) | catalogued as COSV61088027; called by muse, mutect2, varscan2
- GLB1L3 | c.1202C>A p.P401H | Missense Mutation (SNP) | VAF 51/221 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101345140; called by muse, mutect2, varscan2
- GPR21 | c.504G>T p.W168C | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65378956, COSV65379111; called by muse, mutect2, varscan2
- GRAMD4 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.132); catalogued as COSV63030328; called by muse, mutect2, varscan2
- GRB10 | c.1356G>T p.Q452H (on ENST00000398812; = p.Q406H on NM_001001549.3) | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.6); PolyPhen benign (0.14); catalogued as COSV60010669; called by muse, mutect2, varscan2
- GRID1 | c.997G>T p.A333S | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV100022435, COSV60029044; called by muse, mutect2, varscan2
- GRIK2 | c.1229G>T p.G410V | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1165595663, COSV59737232; called by muse, mutect2, varscan2
- GRM5 | c.1057C>A p.P353T | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59605441; called by muse, mutect2, varscan2
- HAO1 | c.103G>T p.E35* | Nonsense Mutation (SNP) | VAF 19/29 reads (66%) | catalogued as COSV66490877; called by muse, mutect2, varscan2
- HECTD4 | c.10144G>A p.D3382N | Missense Mutation (SNP) | VAF 49/96 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV66392154, COSV66401457; called by muse, mutect2, varscan2
- HEG1 | c.2815C>A p.P939T | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.184); catalogued as COSV60762226; called by muse, mutect2, varscan2
- HERC6 | c.2044G>T p.V682F | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV52028667, COSV99986775; called by muse, mutect2, varscan2
- HGF | c.1386T>A p.D462E | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55949693, COSV55949736; called by muse, mutect2, varscan2
- HIPK1 | c.1665C>G p.I555M | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.395); catalogued as COSV61247746; called by muse, mutect2, varscan2
- HPR | c.598G>T p.V200F | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.281); catalogued as COSV57182765; called by muse, mutect2, varscan2
- IGFBP2 | c.603G>C p.Q201H | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.827); catalogued as COSV99288483; called by muse, mutect2
- IL12RB2 | c.193C>G p.R65G | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.03); catalogued as COSV52023530; called by muse, mutect2, varscan2
- IL1RAPL1 | c.635G>T p.G212V | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56244804, COSV56262199, COSV56277180; called by muse, mutect2, varscan2
- IL4R | c.1721G>T p.G574V | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV50144446; called by muse, mutect2, varscan2
- INPP4B | c.20G>T p.G7V | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.086); catalogued as COSV53723386, COSV53733605; called by muse, mutect2, varscan2
- IRS2 | c.3970G>T p.D1324Y | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.809); catalogued as COSV101019196; called by muse, mutect2, varscan2
- IRX1 | c.1160A>G p.N387S | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as COSV57359520; called by muse, mutect2, varscan2
- JAKMIP1 | c.1305G>T p.K435N | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs756604514, COSV51530635; called by muse, mutect2, varscan2
- KALRN | c.4150C>T p.Q1384* | Nonsense Mutation (SNP) | VAF 32/99 reads (32%) | catalogued as COSV53764416; called by muse, mutect2, varscan2
- KCNH8 | c.1122G>T p.W374C | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60458573, COSV60464039; called by muse, mutect2, varscan2
- KDM5A | c.313C>G p.L105V | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV101238744, COSV66992453; called by muse, mutect2, varscan2
- KIRREL1 | c.1172G>T p.G391V | Missense Mutation (SNP) | VAF 56/128 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63285478; called by muse, mutect2, varscan2
- KLHL14 | c.1429+1G>T p.X477_splice | Splice Site (SNP) | VAF 75/145 reads (52%) | catalogued as COSV63832494; called by muse, mutect2, varscan2
- KLK13 | c.313C>A p.H105N | Missense Mutation (SNP) | VAF 47/76 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as COSV99335330; called by muse, mutect2, varscan2
- KRBA1 | c.616A>C p.S206R | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as COSV55441466; called by muse, mutect2, varscan2
- KRT34 | c.475-1G>A p.X159_splice | Splice Site (SNP) | VAF 20/55 reads (36%) | catalogued as COSV67449830; called by muse, mutect2, varscan2
- KRTAP6-1 | c.53G>T p.C18F | Missense Mutation (SNP) | VAF 32/139 reads (23%) | PolyPhen possibly damaging (0.692); catalogued as rs749415607, COSV100228793; called by muse, mutect2, varscan2
- KSR1 | c.1783G>T p.E595* (on ENST00000644974 / NM_001367810.1; = p.E480* on NM_014238.2) | Nonsense Mutation (SNP) | VAF 4/12 reads (33%) | catalogued as COSV52032792; called by muse, mutect2
- KY | c.857G>A p.G286D | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101415023, COSV71017312; called by muse, mutect2, varscan2
- LAMB4 | c.1531G>A p.G511R | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV52719509; called by muse, mutect2, varscan2
- LAMC3 | c.2981G>C p.C994S | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63091335; called by muse, mutect2
- LASP1 | c.538G>T p.A180S | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1327225752, COSV58803766; called by muse, mutect2, varscan2
- LEPR | c.1033G>T p.G345W | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60755125; called by muse, mutect2, varscan2
- LGI2 | c.799C>T p.R267W | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1156361531, COSV66123027; called by muse, mutect2, varscan2
- LIN28B | c.531G>T p.Q177H | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV61495165; called by muse, varscan2
- LRRC37A2 | c.3658C>T p.Q1220* | Nonsense Mutation (SNP) | VAF 22/181 reads (12%) | catalogued as rs1247049794, COSV61003029; called by muse, mutect2, varscan2
- LRRC7 | c.2408C>A p.T803N (on ENST00000651989 / NM_001370785.2; = p.T770N on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.817); catalogued as rs757203769, COSV50459545; called by muse, mutect2, varscan2
- LSS | c.90G>C p.E30D | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs565392079, COSV62700914; called by muse, mutect2
- LTK | c.2536C>A p.P846T | Missense Mutation (SNP) | VAF 30/45 reads (67%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as rs1420605670, COSV53027661; called by muse, mutect2, varscan2
- LYST | c.2630G>T p.G877V | Missense Mutation (SNP) | VAF 52/172 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.333); catalogued as rs886046180, COSV67707053; called by muse, mutect2, varscan2
- MACF1 | c.14599C>G p.L4867V (on ENST00000372915; = p.L2800V on NM_012090.5) | Missense Mutation (SNP) | VAF 44/185 reads (24%) | catalogued as COSV57121381; called by muse, mutect2, varscan2
- MADD | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 37/152 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.056); catalogued as rs1217293963, COSV60624253, COSV60629583; called by muse, mutect2, varscan2
- MAGI1 | c.3463G>T p.D1155Y (on ENST00000402939 / NM_001033057.2; = p.D1184Y on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 126/314 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58326746; called by muse, mutect2, varscan2
- MAN1C1 | c.1861G>A p.D621N | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as rs1371870949, COSV56045110; called by muse, mutect2, varscan2
- MAP1B | c.2370G>T p.K790N | Missense Mutation (SNP) | VAF 24/36 reads (67%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as COSV57099174; called by muse, mutect2, varscan2
- MCC | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.554); catalogued as COSV101342710, COSV68727315; called by muse, mutect2
- ME2 | c.272G>C p.R91T | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.967); catalogued as COSV58423253; called by muse, mutect2, varscan2
- MELTF | c.1822C>T p.R608* | Nonsense Mutation (SNP) | VAF 15/32 reads (47%) | catalogued as rs1417384723, COSV56381413; called by muse, mutect2, varscan2
- MGA | c.2104A>T p.R702* | Nonsense Mutation (SNP) | VAF 8/14 reads (57%) | catalogued as COSV54953890; called by muse, mutect2
- MKX | c.613G>C p.E205Q | Missense Mutation (SNP) | VAF 49/102 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV65392199; called by muse, mutect2, varscan2
- MLH1 | c.1763T>G p.L588R | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as CM001244, COSV51618128; called by muse, mutect2, varscan2
- MRM2 | c.258G>A p.W86* | Nonsense Mutation (SNP) | VAF 11/30 reads (37%) | catalogued as COSV54248123; called by muse, mutect2
- MRPL39 | c.749G>C p.R250T | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.352); catalogued as COSV56260790; called by muse, mutect2
- MS4A12 | c.277-1G>T p.X93_splice | Splice Site (SNP) | VAF 42/178 reads (24%) | catalogued as COSV50014488; called by muse, mutect2, varscan2
- MUC16 | c.1595A>T p.Q532L | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.598); catalogued as COSV67466464; called by muse, mutect2, varscan2
- MYH2 | c.219G>T p.K73N | Missense Mutation (SNP) | VAF 56/92 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV55438462; called by muse, mutect2, varscan2
- MYH8 | c.2011C>T p.H671Y | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1169981995, COSV67965246, COSV67970009; called by muse, mutect2, varscan2
- MYO16 | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.065); catalogued as COSV51794599, COSV99193599; called by muse, mutect2, varscan2
- NAALAD2 | c.1190G>T p.S397I | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.095); catalogued as COSV58961145; called by muse, mutect2, varscan2
- NDE1 | c.379G>T p.A127S | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.795); catalogued as COSV61272522; called by muse, mutect2, varscan2
- NEU4 | c.547C>A p.R183S (on ENST00000391969 / NM_001167602.3; = p.R195S on NM_080741.4) | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.154); catalogued as COSV100372104; called by muse, mutect2, varscan2
- NGDN | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs148302816; called by muse, mutect2, varscan2
- NMUR2 | c.799A>C p.N267H | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.455); catalogued as COSV54919360; called by muse, mutect2, varscan2
- NPY1R | c.601C>T p.Q201* | Nonsense Mutation (SNP) | VAF 10/28 reads (36%) | catalogued as COSV56714528; called by muse, mutect2, varscan2
- NUDT14 | c.283G>T p.G95C | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV59650384; called by muse, mutect2, varscan2
- OLFM4 | c.358-1G>T p.X120_splice | Splice Site (SNP) | VAF 11/45 reads (24%) | catalogued as COSV54577406; called by muse, mutect2, varscan2
- OR13A1 | c.872T>A p.L291* | Nonsense Mutation (SNP) | VAF 9/58 reads (16%) | catalogued as COSV65572397; called by muse, mutect2, varscan2
- OR2B6 | c.59G>T p.R20L | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV55128930; called by muse, mutect2, varscan2
- OR2G3 | c.526C>A p.H176N | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV100180505, COSV60681697; called by muse, mutect2, varscan2
- OR2M5 | c.20C>A p.T7N | Missense Mutation (SNP) | VAF 90/261 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.033); catalogued as COSV63546282; called by muse, mutect2, varscan2
- OR2T27 | c.173C>A p.P58H | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61283957; called by muse, mutect2, varscan2
- OR2T3 | c.621C>A p.C207* | Nonsense Mutation (SNP) | VAF 95/254 reads (37%) | catalogued as COSV62082480, COSV62083087; called by muse, mutect2, varscan2
- OR2T6 | c.22T>A p.L8M | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.017); catalogued as COSV63216312; called by muse, mutect2, varscan2
- OR4C15 | c.544C>G p.P182A (on ENST00000314644; = p.P128A on NM_001001920.2) | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.168); catalogued as COSV58952901; called by muse, mutect2, varscan2
- OR4C46 | c.341C>A p.T114N | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.655); catalogued as COSV60219406; called by muse, mutect2, varscan2
- OR4K15 | c.61C>A p.L21I | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.062); catalogued as COSV100521074; called by muse, mutect2, varscan2
- OR4N2 | c.706G>T p.A236S | Missense Mutation (SNP) | VAF 53/148 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60051546; called by muse, mutect2, varscan2
- OR4S1 | c.757A>G p.M253V | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100180273; called by muse, mutect2, varscan2
- OR5H2 | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 99/319 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as rs759676483, COSV62350792; called by muse, mutect2, varscan2
- OR5I1 | c.178C>G p.P60A | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100041503, COSV100041697; called by muse, mutect2, varscan2
- OR5L1 | c.676C>A p.L226M | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.988); catalogued as COSV61733889; called by muse, mutect2, varscan2
- OR8H2 | c.190C>T p.L64F | Missense Mutation (SNP) | VAF 39/204 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57943721; called by muse, mutect2, varscan2
- OR8J3 | c.236C>A p.P79H | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100040502, COSV100040802; called by muse, mutect2, varscan2
- OR8J3 | c.235C>A p.P79T | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV100040895, COSV56880985; called by muse, mutect2, varscan2
- OR9G1 | c.506G>T p.R169L | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.152); catalogued as COSV56450650; called by muse, varscan2
- PALD1 | c.1993C>T p.Q665* | Nonsense Mutation (SNP) | VAF 33/83 reads (40%) | catalogued as COSV54973613; called by muse, mutect2, varscan2
- PAPOLG | c.1334T>C p.V445A | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as COSV53182808; called by muse, mutect2, varscan2
- PCDHB6 | c.1675G>A p.V559M | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV50692259; called by muse, mutect2, varscan2
- PCDHB7 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.049); catalogued as COSV50761582; called by muse, mutect2, varscan2
- PCDHB8 | c.1419C>A p.S473R | Missense Mutation (SNP) | VAF 72/840 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.964); catalogued as COSV50768308; called by muse, mutect2
- PCSK2 | c.1331A>G p.Y444C | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52732753; called by muse, mutect2, varscan2
- PELP1 | c.2206G>A p.E736K | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.344); catalogued as COSV52591845; called by muse, mutect2, varscan2
- PGAM5 | c.250G>C p.E84Q | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as COSV58202127; called by muse, mutect2, varscan2
- PGGT1B | c.655C>T p.H219Y | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56973883; called by muse, mutect2, varscan2
- PGM5 | c.1308G>T p.E436D | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as COSV67167697; called by muse, mutect2, varscan2
- PHF8 | c.1573G>A p.G525S (on ENST00000357988 / NM_001184896.1; = p.G489S on NM_015107.3) | Missense Mutation (SNP) | VAF 23/36 reads (64%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV57681730; called by muse, mutect2, varscan2
- PLSCR4 | c.430G>T p.D144Y | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV61608000; called by muse, mutect2, varscan2
- PM20D2 | c.685G>C p.D229H | Missense Mutation (SNP) | VAF 39/57 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51530632; called by muse, mutect2, varscan2
- POLQ | c.5989G>T p.D1997Y | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51752163; called by muse, mutect2, varscan2
- POLQ | c.3847G>T p.E1283* | Nonsense Mutation (SNP) | VAF 40/136 reads (29%) | catalogued as COSV51752175; called by muse, mutect2, varscan2
- POLR1F | c.854A>G p.Q285R | Missense Mutation (SNP) | VAF 155/508 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV55998506; called by muse, mutect2, varscan2
- POM121L12 | c.178C>A p.Q60K | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.039); catalogued as COSV68692971; called by muse, mutect2, varscan2
- POTEE | c.1635C>A p.H545Q | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.294); catalogued as COSV58230928, COSV58232373; called by mutect2, varscan2
- PPFIA4 | c.2275C>G p.R759G (on ENST00000447715; = p.R760G on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV55315131, COSV55318379; called by muse, mutect2, varscan2
- PRDM9 | c.745G>T p.G249W | Missense Mutation (SNP) | VAF 53/88 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV57006399; called by muse, mutect2, varscan2
- PRKCB | c.1144G>A p.D382N | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57780069; called by muse, mutect2, varscan2
- PRKD1 | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs1339474902, COSV59569199; called by muse, mutect2, varscan2
- PROKR1 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771068433, COSV58137569; called by muse, mutect2, varscan2
- PROX1 | c.1190G>T p.G397V | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.935); catalogued as COSV54778077; called by muse, mutect2, varscan2
- PRSS16 | c.246G>A p.W82* | Nonsense Mutation (SNP) | VAF 19/27 reads (70%) | catalogued as COSV57915523; called by muse, mutect2, varscan2
- PTPRZ1 | c.5785G>C p.V1929L | Missense Mutation (SNP) | VAF 71/118 reads (60%) | SIFT deleterious (0.05); PolyPhen benign (0.076); catalogued as COSV66436756; called by muse, varscan2
- PUS7L | c.425G>T p.C142F | Missense Mutation (SNP) | VAF 51/67 reads (76%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs760952483, COSV61261908; called by muse, mutect2, varscan2
- PXDNL | c.2109C>G p.I703M | Missense Mutation (SNP) | VAF 28/43 reads (65%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.944); catalogued as COSV62487471; called by muse, mutect2, varscan2
- RAD54B | c.2359G>T p.G787C | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV60251371; called by muse, mutect2, varscan2
- RAP1GAP | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV99265442; called by muse, mutect2, varscan2
- RBM19 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55692281; called by muse, mutect2, varscan2
- RDH10 | c.613G>T p.A205S | Missense Mutation (SNP) | VAF 31/213 reads (15%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.482); catalogued as COSV99536358; called by muse, mutect2, varscan2
- REG3A | c.331C>A p.Q111K | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59412434; called by muse, mutect2, varscan2
- REG3G | c.127G>A p.G43S | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.151); catalogued as COSV55449069, COSV55450717; called by muse, mutect2, varscan2
- RGS20 | c.373G>T p.G125C | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); catalogued as COSV52017015; called by muse, mutect2, varscan2
- RNF112 | c.769A>T p.S257C | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV71978790; called by mutect2, varscan2
- RNF113B | c.129C>A p.H43Q | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV99940367; called by muse, mutect2, varscan2
- RNF25 | c.769G>T p.E257* | Nonsense Mutation (SNP) | VAF 34/64 reads (53%) | catalogued as COSV55305971, COSV55307422; called by muse, mutect2, varscan2
- RREB1 | c.526C>G p.H176D | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.325); catalogued as COSV58558140; called by muse, mutect2, varscan2
- RXFP3 | c.271G>T p.V91L | Missense Mutation (SNP) | VAF 62/97 reads (64%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.751); catalogued as COSV57505616; called by muse, mutect2, varscan2
- SACS | c.7490G>T p.G2497V | Missense Mutation (SNP) | VAF 54/150 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV66540058; called by muse, mutect2, varscan2
- SALL3 | c.1490T>G p.I497S | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV73306052; called by muse, mutect2, varscan2
- SCN11A | c.1189G>C p.A397P | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56570506; called by muse, mutect2, varscan2
- SCN7A | c.4508C>G p.S1503C | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV101313274; called by muse, mutect2, varscan2
- SEC14L1 | c.928G>C p.V310L | Missense Mutation (SNP) | VAF 54/118 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.196); catalogued as COSV66722327; called by muse, mutect2, varscan2
- SEMA3A | c.2229C>A p.N743K | Missense Mutation (SNP) | VAF 66/172 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV54870807; called by muse, mutect2, varscan2
- SEMA3A | c.1115G>A p.R372K | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0.054); catalogued as rs1257380600, COSV54870818; called by muse, mutect2, varscan2
- SEMA3C | c.1042G>T p.V348L | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV54846658; called by muse, mutect2, varscan2
- SEMA6A | c.2651G>A p.R884Q | Missense Mutation (SNP) | VAF 60/116 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs754494225, COSV56711270; called by muse, varscan2
- SEPTIN14 | c.1127A>T p.D376V | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV66427771; called by muse, mutect2, varscan2
- SERPINA10 | c.868C>A p.L290M | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56227674, COSV56228319; called by muse, mutect2, varscan2
- SGCD | c.787T>A p.C263S (on ENST00000435422 / NM_001128209.2; = p.C264S on NM_000337.5) | Missense Mutation (SNP) | VAF 45/70 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61908723; called by muse, mutect2, varscan2
- SGO1 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99768352; called by muse, mutect2, varscan2
- SH3TC2 | c.833G>A p.G278D | Missense Mutation (SNP) | VAF 64/114 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757292503, COSV100101936; called by muse, mutect2, varscan2
- SIN3A | c.613C>G p.P205A | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as COSV64582974; called by muse, mutect2, varscan2
- SLC17A4 | c.1171A>T p.S391C | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV64956229; called by muse, mutect2
- SLC4A4 | c.1588G>T p.G530* (on ENST00000264485 / NM_001098484.3; = p.G486* on NM_003759.4) | Nonsense Mutation (SNP) | VAF 22/126 reads (17%) | catalogued as CM083160, COSV52618591, COSV52624428; called by muse, mutect2, varscan2
- SLC6A3 | c.215C>T p.S72F | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1560928848, COSV54364295; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SNX7 | c.451G>C p.A151P | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); catalogued as COSV60268518; called by muse, mutect2, varscan2
- SOX5 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58629895; called by muse, mutect2, varscan2
- SPA17 | c.224A>C p.E75A | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV99907176; called by muse, mutect2, varscan2
- SPATA31A1 | c.3319A>T p.I1107F | Missense Mutation (SNP) | VAF 145/319 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as COSV100885049, COSV66533902; called by muse, mutect2, varscan2
- SPATA31D1 | c.2101G>T p.G701C | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); catalogued as COSV61195899; called by muse, mutect2, varscan2
- SPEG | c.3479C>A p.A1160D | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.422); catalogued as COSV56669084; called by muse, mutect2, varscan2
- SPTA1 | c.2759C>T p.P920L | Missense Mutation (SNP) | VAF 27/195 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as COSV63753228; called by muse, mutect2, varscan2
- SRCAP | c.3263C>T p.S1088F | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.276); catalogued as rs1277495122, COSV52672714; called by muse, mutect2, varscan2
- SRRM2 | c.3332G>A p.R1111K | Missense Mutation (SNP) | VAF 41/63 reads (65%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV57073328; called by muse, mutect2, varscan2
- TACC3 | c.1040C>T p.T347I | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.28); catalogued as COSV57604892; called by muse, mutect2, varscan2
- TARBP1 | c.4552C>G p.L1518V | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.759); catalogued as rs1447490235, COSV50184638; called by muse, mutect2, varscan2
- TDRD3 | c.764G>T p.R255I | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs888064212, COSV52156877, COSV99541117; called by muse, mutect2, varscan2
- THSD7A | c.316A>T p.N106Y | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.141); catalogued as COSV70264843; called by muse, mutect2, varscan2
- TIAM1 | c.3124C>A p.R1042S | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54551399, COSV54552811; called by muse, mutect2, varscan2
- TKTL2 | c.1701C>A p.Y567* | Nonsense Mutation (SNP) | VAF 17/67 reads (25%) | catalogued as COSV54918858; called by muse, mutect2, varscan2
- TLL1 | c.2935G>T p.D979Y | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV50280086; called by muse, mutect2, varscan2
- TLR4 | c.1122C>A p.S374R (on ENST00000355622 / NM_138554.5; = p.S334R on NM_003266.4) | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.408); catalogued as COSV100842907, COSV62923288, COSV62924132; called by muse, mutect2, varscan2
- TLR8 | c.2125G>T p.D709Y (on ENST00000218032 / NM_138636.5; = p.D727Y on NM_016610.4) | Missense Mutation (SNP) | VAF 28/44 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV54318003, COSV99486870; called by muse, mutect2, varscan2
- TNR | c.800C>T p.P267L | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.89); PolyPhen benign (0.01); catalogued as COSV54885881; called by muse, mutect2, varscan2
- TRIM10 | c.1217G>A p.R406K | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.82); catalogued as COSV100939730; called by muse, mutect2, varscan2
- TTLL4 | c.2685G>T p.M895I | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.262); catalogued as COSV51436476; called by muse, mutect2, varscan2
- UBE2D3 | c.138A>C p.Q46H | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.014); catalogued as COSV57661773; called by muse, mutect2, varscan2
- UGGT2 | c.4459G>C p.E1487Q | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65074949; called by muse, mutect2, varscan2
- UGT2B11 | c.163G>C p.V55L | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as COSV71423388; called by muse, mutect2, varscan2
- VPS8 | c.2854G>A p.E952K (on ENST00000625842 / NM_001349294.1; = p.E950K on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV54985961; called by muse, mutect2, varscan2
- WASF1 | c.777G>T p.Q259H | Missense Mutation (SNP) | VAF 33/50 reads (66%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.969); catalogued as COSV63935444, COSV63935799; called by muse, mutect2, varscan2
- WDTC1 | c.238A>C p.K80Q | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); catalogued as COSV60088327; called by muse, mutect2, varscan2
- ZAN | c.235G>A p.G79R | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs774557339, COSV61809202; called by muse, mutect2, varscan2
- ZFYVE28 | c.1011C>A p.Y337* | Nonsense Mutation (SNP) | VAF 24/52 reads (46%) | catalogued as COSV52111250; called by muse, mutect2, varscan2
- ZIK1 | c.651del p.K218Rfs*65 | Frame Shift Del (DEL) | VAF 23/42 reads (55%) | catalogued as COSV100277492; called by mutect2, pindel, varscan2
- ZNF226 | c.2233C>G p.H745D | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56196620; called by muse, mutect2
- ZNF234 | c.1021G>C p.E341Q | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as COSV70603293; called by muse, mutect2, varscan2
- ZNF292 | c.1252G>A p.D418N | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV60539486; called by muse, mutect2, varscan2
- ZNF318 | c.6769C>G p.Q2257E | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.121); catalogued as rs778058831, COSV58932644; called by muse, mutect2, varscan2
- ZNF436 | c.905G>T p.G302V | Missense Mutation (SNP) | VAF 56/102 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58358559; called by muse, mutect2, varscan2
- ZNF451 | c.1047G>C p.K349N | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV100674950; called by muse, mutect2, varscan2
- ZNF598 | c.2668G>C p.D890H | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV50192264; called by muse, mutect2, varscan2
- ZNF622 | c.57G>T p.Q19H | Missense Mutation (SNP) | VAF 63/113 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58074108; called by muse, mutect2, varscan2
- ZNF75D | c.450G>T p.L150F | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV66132760; called by muse, mutect2, varscan2
- ZNF804A | c.3278C>A p.T1093N | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1385890236, COSV56449077; called by muse, mutect2, varscan2
- ZNF823 | c.1042C>T p.R348* (on ENST00000341191 / NM_001297610.2; = p.R304* on NM_017507.2) | Nonsense Mutation (SNP) | VAF 30/101 reads (30%) | catalogued as rs200817135, COSV57873224; called by muse, mutect2, varscan2
- ZWINT | c.817G>A p.D273N | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.167); catalogued as COSV59185420, COSV59185845; called by muse, mutect2, varscan2
- ATP1B1 | c.606dup p.K203Efs*3 | Frame Shift Ins (INS) | VAF 27/87 reads (31%) | called by mutect2, pindel, varscan2
- CTNNA2 | c.379del p.A127Qfs*8 | Frame Shift Del (DEL) | VAF 22/77 reads (29%) | called by mutect2, pindel, varscan2
- DST | c.13688C>A p.A4563E (on ENST00000361203 / NM_001374722.1; = p.A2151E on NM_015548.5) | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.09); called by mutect2, varscan2
- FRG2 | c.641G>C p.R214P | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- IGLC2 | c.212A>T p.Y71F | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- IGLV4-3 | c.217G>T p.G73C | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KIR3DL3 | c.760C>A p.H254N | Missense Mutation (SNP) | VAF 110/142 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- MATN3 | c.796G>T p.D266Y | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- MUC5AC | c.14050G>T p.V4684L | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.18); called by mutect2, varscan2
- NFXL1 | c.1757dup p.L586Ffs*14 | Frame Shift Ins (INS) | VAF 13/93 reads (14%) | called by pindel, varscan2*
- PLEKHG5 | c.1441G>T p.G481C (on ENST00000400915 / NM_001042663.3; = p.G444C on NM_020631.6) | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- ROR2 | c.2704_2722del p.E902Pfs*82 | Frame Shift Del (DEL) | VAF 17/104 reads (16%) | called by mutect2, pindel
- THOC3 | c.304_314del p.V102Lfs*6 | Frame Shift Del (DEL) | VAF 11/52 reads (21%) | called by mutect2, pindel, varscan2
- TRAV26-1 | c.86G>T p.C29F | Missense Mutation (SNP) | VAF 53/119 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TRAV29DV5 | c.279C>A p.N93K | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.461); called by muse, mutect2
- UNC45B | c.2485del p.A829Pfs*3 | Frame Shift Del (DEL) | VAF 16/42 reads (38%) | called by pindel, varscan2
- AACS | c.1593C>T p.T531= | Silent (SNP) | VAF 16/24 reads (67%) | catalogued as rs575536966, COSV55536804; called by muse, mutect2, varscan2
- ABCA8 | c.612T>A p.V204= | Silent (SNP) | VAF 19/92 reads (21%) | catalogued as COSV52201444; called by muse, mutect2, varscan2
- ACSM5 | c.756G>T p.V252= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as COSV59371525; called by muse, mutect2
- ADAM19 | c.2373C>A p.P791= | Silent (SNP) | VAF 21/50 reads (42%) | catalogued as COSV57430251; called by muse, mutect2, varscan2
- ANKRD23 | c.402A>C p.G134= | Silent (SNP) | VAF 21/115 reads (18%) | catalogued as COSV58412636; called by muse, mutect2, varscan2
- AOAH | c.1575C>A p.P525= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as COSV51741626, COSV51751897; called by muse, mutect2, varscan2
- ASXL3 | c.5157T>A p.A1719= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV52466440; called by muse, mutect2, varscan2
- ATP1A2 | c.2739C>T p.F913= | Silent (SNP) | VAF 41/253 reads (16%) | catalogued as COSV63403788; called by muse, mutect2, varscan2
- ATRNL1 | c.2118C>A p.T706= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as COSV61804464; called by muse, mutect2, varscan2
- B3GLCT | c.1323C>T p.F441= | Silent (SNP) | VAF 98/258 reads (38%) | catalogued as COSV58455295; called by muse, mutect2, varscan2
- BCAN | c.1482T>A p.S494= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as COSV61256900; called by muse, mutect2, varscan2
- BCL2 | c.375C>T p.T125= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as rs972409029, COSV61379925; called by muse, mutect2, varscan2
- C11orf42 | c.690C>T p.L230= | Silent (SNP) | VAF 21/91 reads (23%) | catalogued as COSV56411457; called by muse, mutect2, varscan2
- C8A | c.879C>T p.F293= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as COSV63484069; called by muse, mutect2
- CADM3 | c.1140C>T p.I380= (on ENST00000368125 / NM_001127173.3; = p.I414= on NM_021189.5) | Silent (SNP) | VAF 14/116 reads (12%) | catalogued as COSV63672821; called by muse, mutect2, varscan2
- CBLN2 | c.171C>T p.P57= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV54051232; called by muse, mutect2
- CD83 | c.501G>T p.R167= | Silent (SNP) | VAF 14/137 reads (10%) | catalogued as COSV64788166; called by muse, mutect2, varscan2
- CDC25A | c.1083T>A p.S361= | Silent (SNP) | VAF 84/225 reads (37%) | catalogued as COSV56770652; called by muse, mutect2, varscan2
- CDC42BPG | c.1287G>A p.L429= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as rs147432161; called by muse, mutect2, varscan2
- CFAP65 | c.5010G>A p.Q1670= | Silent (SNP) | VAF 24/105 reads (23%) | catalogued as COSV58561044; called by muse, mutect2, varscan2
- CHAC2 | c.150G>A p.V50= | Silent (SNP) | VAF 20/163 reads (12%) | catalogued as COSV99712165; called by muse, mutect2, varscan2
- COL22A1 | c.1431C>A p.S477= | Silent (SNP) | VAF 8/90 reads (9%) | catalogued as COSV57326454; called by muse, mutect2
- CPS1 | c.3249C>A p.I1083= | Silent (SNP) | VAF 45/108 reads (42%) | catalogued as rs751008875, COSV51810408, COSV51825930; called by muse, mutect2, varscan2
- DCDC1 | c.2001C>T p.V667= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs1336239744, COSV60842621; called by muse, mutect2, varscan2
- DNAJC6 | c.1203G>A p.T401= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as rs148673423; called by muse, mutect2, varscan2
- ELOA2 | c.534C>A p.L178= | Silent (SNP) | VAF 34/82 reads (41%) | catalogued as rs983390452, COSV55299215; called by muse, mutect2, varscan2
- ETV6 | c.561G>C p.T187= | Silent (SNP) | VAF 74/267 reads (28%) | catalogued as COSV67150090, COSV67152109; called by muse, mutect2, varscan2
- F12 | c.504C>T p.A168= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV53691398; called by muse, mutect2
- FBLN5 | c.684C>T p.F228= | Silent (SNP) | VAF 6/114 reads (5%) | catalogued as COSV50903705; called by muse, mutect2
- FCGBP | c.6042C>A p.T2014= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as COSV99662868; called by muse, mutect2, varscan2
- GABRA1 | c.480G>A p.L160= | Silent (SNP) | VAF 26/46 reads (57%) | catalogued as COSV50104471; called by muse, mutect2, varscan2
- GABRA5 | c.507C>T p.I169= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV59479753; called by muse, mutect2, varscan2
- GRIK3 | c.213G>A p.R71= | Silent (SNP) | VAF 30/144 reads (21%) | catalogued as COSV66140023; called by muse, mutect2, varscan2
- HECW1 | c.1950G>T p.T650= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as COSV67827195, COSV67829692; called by muse, mutect2, varscan2
- HTR3A | c.103C>T p.L35= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV55469505; called by muse, mutect2, varscan2
- ICAM5 | c.408G>A p.E136= | Silent (SNP) | VAF 33/151 reads (22%) | catalogued as COSV53425071, COSV53427408; called by muse, mutect2, varscan2
- KCNC4 | c.1611G>T p.R537= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as COSV63925640; called by muse, varscan2
- KCNQ2 | c.1401C>A p.P467= (on ENST00000359125 / NM_172107.4; = p.P439= on NM_004518.6) | Silent (SNP) | VAF 42/68 reads (62%) | catalogued as COSV60545074; called by muse, mutect2, varscan2
- KCNU1 | c.2901C>A p.S967= | Silent (SNP) | VAF 24/203 reads (12%) | catalogued as COSV67755925; called by muse, mutect2, varscan2
- KHDRBS2 | c.273A>T p.L91= | Silent (SNP) | VAF 11/90 reads (12%) | catalogued as COSV55454170, COSV55471939; called by muse, mutect2, varscan2
- KIR3DL2 | c.645C>T p.I215= | Silent (SNP) | VAF 203/299 reads (68%) | catalogued as rs752693017, COSV54393619; called by muse, mutect2, varscan2
- KIRREL2 | c.609C>T p.V203= | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as COSV52876486; called by muse, mutect2, varscan2
- LAP3 | c.879C>T p.I293= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as COSV56899890; called by muse, mutect2, varscan2
- MAP3K3 | c.480C>T p.P160= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as rs780212319, COSV62280710; called by muse, mutect2, varscan2
- NMUR1 | c.1059C>A p.P353= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as COSV59403651, COSV59404268; called by muse, mutect2, varscan2
- NOL8 | c.2235G>T p.S745= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV100694596; called by muse, mutect2, varscan2
- OPALIN | c.345G>T p.V115= | Silent (SNP) | VAF 34/155 reads (22%) | catalogued as COSV64520574; called by muse, mutect2, varscan2
- OR10G3 | c.831C>T p.P277= | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as COSV100336118; called by muse, mutect2, varscan2
- OR10R2 | c.654G>C p.V218= | Silent (SNP) | VAF 29/204 reads (14%) | catalogued as rs768702937, COSV63768811, COSV63768829; called by muse, mutect2, varscan2
- OR13C5 | c.480A>C p.T160= | Silent (SNP) | VAF 23/91 reads (25%) | catalogued as COSV66164605; called by muse, mutect2, varscan2
- OR1M1 | c.135C>T p.I45= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV70036899; called by muse, mutect2, varscan2
- OR4C6 | c.792C>T p.P264= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as COSV58603399, COSV58604095; called by muse, mutect2, varscan2
- OR4K15 | c.60C>A p.S20= | Silent (SNP) | VAF 18/81 reads (22%) | catalogued as COSV100521068; called by muse, mutect2, varscan2
- OR51A4 | c.531C>T p.S177= | Silent (SNP) | VAF 19/153 reads (12%) | catalogued as rs373266822, COSV66749478; called by muse, mutect2, varscan2
- OR52I2 | c.921A>T p.L307= | Silent (SNP) | VAF 32/118 reads (27%) | catalogued as COSV57045023; called by muse, mutect2, varscan2
- OTX2 | c.468C>T p.S156= (on ENST00000408990 / NM_172337.3; = p.S164= on NM_021728.4) | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as COSV59766122; called by muse, mutect2, varscan2
- PALD1 | c.771C>A p.P257= | Silent (SNP) | VAF 36/86 reads (42%) | catalogued as COSV54973599; called by muse, mutect2, varscan2
- PAPPA2 | c.5052C>G p.P1684= | Silent (SNP) | VAF 26/67 reads (39%) | catalogued as COSV62795860, COSV62797765; called by muse, mutect2, varscan2
- PAQR6 | c.708C>G p.L236= (on ENST00000292291 / NM_001272108.2; = p.L130= on NM_024897.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as COSV52745238; called by muse, mutect2, varscan2
- PCDH10 | c.2917C>T p.L973= | Silent (SNP) | VAF 27/85 reads (32%) | catalogued as COSV52094183; called by muse, mutect2, varscan2
- PCNX1 | c.4494T>C p.S1498= | Silent (SNP) | VAF 81/174 reads (47%) | catalogued as COSV53094887; called by muse, mutect2, varscan2
- PKHD1L1 | c.8304G>A p.G2768= | Silent (SNP) | VAF 51/84 reads (61%) | catalogued as rs747019693, COSV65743060, COSV65745659; called by muse, mutect2, varscan2
- PLCH2 | c.1209C>T p.I403= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV53939794; called by muse, mutect2, varscan2
- PNPLA7 | c.1344G>T p.S448= | Silent (SNP) | VAF 33/76 reads (43%) | catalogued as COSV52997143, COSV52998920; called by muse, mutect2, varscan2
- PRKD1 | c.1731C>T p.I577= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV59569182; called by muse, mutect2, varscan2
- PSG5 | c.459C>A p.I153= | Silent (SNP) | VAF 150/237 reads (63%) | catalogued as COSV61654222; called by muse, mutect2, varscan2
- PTDSS1 | c.711C>T p.C237= | Silent (SNP) | VAF 79/128 reads (62%) | catalogued as rs911510872, COSV61264801; called by muse, mutect2, varscan2
- RAET1G | c.444C>T p.F148= | Silent (SNP) | VAF 6/89 reads (7%) | catalogued as COSV66274397; called by muse, mutect2
- RBP3 | c.432G>T p.L144= | Silent (SNP) | VAF 10/89 reads (11%) | called by muse, mutect2, varscan2
- RNASE7 | c.48G>T p.L16= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV100069695; called by muse, mutect2, varscan2
- RTL4 | c.336C>A p.I112= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as COSV61206522; called by muse, mutect2, varscan2
- SCG2 | c.1692G>A p.P564= | Silent (SNP) | VAF 36/91 reads (40%) | catalogued as rs749325832, COSV59540079; called by muse, mutect2, varscan2
- SEMA5A | c.2967C>G p.V989= | Silent (SNP) | VAF 14/180 reads (8%) | catalogued as COSV66793458; called by muse, mutect2
- SEMA6A | c.2550G>T p.L850= | Silent (SNP) | VAF 113/221 reads (51%) | catalogued as COSV56711288; called by muse, varscan2
- SLC12A5 | c.1902C>T p.F634= (on ENST00000454036 / NM_001134771.2; = p.F611= on NM_020708.5) | Silent (SNP) | VAF 11/210 reads (5%) | catalogued as COSV54793829, COSV54798858; called by muse, mutect2
- SLC12A9 | c.1611G>T p.L537= | Silent (SNP) | VAF 9/86 reads (10%) | catalogued as COSV51933450; called by muse, mutect2, varscan2
- SNTB1 | c.705C>T p.F235= | Silent (SNP) | VAF 7/86 reads (8%) | catalogued as COSV67326201; called by muse, mutect2
- SYNGR3 | c.417G>A p.T139= | Silent (SNP) | VAF 11/18 reads (61%) | catalogued as rs201344943, COSV99937063; called by muse, mutect2, varscan2
- TARS1 | c.681G>T p.L227= | Silent (SNP) | VAF 81/141 reads (57%) | catalogued as COSV54309208; called by muse, mutect2, varscan2
- TENM2 | c.5331G>A p.R1777= (on ENST00000518659 / NM_001122679.2; = p.R1538= on NM_001080428.3) | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as COSV69130536; called by muse, mutect2, varscan2
- THSD7A | c.4929A>T p.R1643= | Silent (SNP) | VAF 44/121 reads (36%) | catalogued as COSV68471836; called by muse, mutect2, varscan2
- TMCC3 | c.843G>T p.L281= | Silent (SNP) | VAF 27/53 reads (51%) | catalogued as COSV54154514; called by muse, mutect2, varscan2
- TREML1 | c.120C>T p.Y40= | Silent (SNP) | VAF 28/56 reads (50%) | catalogued as rs777476176, COSV58294567; called by muse, mutect2, varscan2
- TSHZ2 | c.2736G>T p.G912= | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as COSV61588789; called by muse, mutect2, varscan2
- TSHZ3 | c.1107G>A p.Q369= | Silent (SNP) | VAF 14/178 reads (8%) | catalogued as COSV53671795; called by muse, mutect2
- UMOD | c.1446G>A p.E482= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs1329446673, COSV56775761; called by muse, mutect2, varscan2
- UNC79 | c.7296C>T p.A2432= (on ENST00000393151 / NM_001346218.2; = p.A2255= on NM_020818.5) | Silent (SNP) | VAF 23/79 reads (29%) | catalogued as COSV56388272; called by muse, mutect2, varscan2
- USP15 | c.1575A>T p.I525= (on ENST00000280377 / NM_001351159.2; = p.I496= on NM_006313.3 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 44/100 reads (44%) | catalogued as COSV54792274; called by muse, mutect2, varscan2
- USP21 | c.186G>T p.R62= | Silent (SNP) | VAF 43/110 reads (39%) | catalogued as COSV57088687; called by muse, mutect2, varscan2
- UTS2 | c.78C>T p.S26= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as COSV99276835; called by muse, mutect2, varscan2
- WNK2 | c.6177G>T p.S2059= (on ENST00000297954 / NM_001282394.1; = p.S2022= on NM_006648.3) | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV52941841; called by muse, mutect2, varscan2
- XKR7 | c.1245C>T p.L415= | Silent (SNP) | VAF 15/78 reads (19%) | catalogued as COSV73813186; called by muse, mutect2, varscan2
- ADAM20 | c.-33C>G | 5'UTR (SNP) | VAF 45/104 reads (43%) | catalogued as COSV56455019; called by muse, mutect2, varscan2
- AIRE | c.880-205G>C | Intron (SNP) | VAF 34/120 reads (28%) | catalogued as COSV99381230; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73847081 C>G | 5'Flank (SNP) | VAF 7/16 reads (44%) | called by muse, mutect2, varscan2
- ERCC6 | c.1397+8695G>A | Intron (SNP) | VAF 16/76 reads (21%) | catalogued as COSV63390144; called by muse, mutect2, varscan2
- KDELR2 | c.*32C>T | 3'UTR (SNP) | VAF 20/129 reads (16%) | catalogued as rs1182852584, COSV99330648; called by muse, mutect2, varscan2
- MC3R | c.-66G>C | 5'UTR (SNP) | VAF 45/226 reads (20%) | catalogued as COSV99710669; called by muse, mutect2, varscan2
- MIR147A | n.65G>T | RNA (SNP) | VAF 15/44 reads (34%) | called by muse, mutect2, varscan2
- MYL3 | chr3:46832982 C>A | 3'Flank (SNP) | VAF 29/65 reads (45%) | catalogued as COSV101451261, COSV70133759; called by muse, mutect2, varscan2
- SON | c.6657+220G>T | Intron (SNP) | VAF 27/59 reads (46%) | catalogued as rs763022057, COSV51656017, COSV99278932; called by muse, mutect2, varscan2
- ZNF783 | c.802+3597C>T | Intron (SNP) | VAF 12/56 reads (21%) | catalogued as rs1366579751, COSV100954261; called by muse, mutect2
